Somatic mutation profile of tumor specimen TCGA-95-A4VK-01A (aliquot TCGA-95-A4VK-01A-11D-A25L-08) from TCGA case TCGA-95-A4VK, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 74.0 years (27,040 days).
Specimen TCGA-95-A4VK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c15e783a-6783-4764-b9b1-afa1dfed818d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-95-A4VK-10A (Blood Derived Normal), aliquot TCGA-95-A4VK-10A-01D-A25L-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/42e75696-f91f-4815-add7-2cff3af0e4c1

The open-access MAF lists 281 somatic variants for this specimen: 214 protein-altering or splice-affecting, 61 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 183, Silent 61, Nonsense Mutation 14, Splice Site 8, Frame Shift Del 7, RNA 6, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB5 | c.3148G>C p.G1050R (on ENST00000404938 / NM_001163941.2; = p.G605R on NM_178559.6) | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99327764; called by muse, mutect2, varscan2
- ACTL6B | c.166G>A p.G56R | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.879); catalogued as COSV99355475, COSV99355708; called by muse, mutect2, varscan2
- ACTRT1 | c.940C>A p.L314I | Missense Mutation (SNP) | VAF 53/136 reads (39%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.773); catalogued as COSV100947520; called by muse, mutect2, varscan2
- ADAMTS20 | c.1780T>C p.Y594H | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as rs1402998742, COSV101239059; called by muse, mutect2, varscan2
- AGK | c.976-1G>T p.X326_splice | Splice Site (SNP) | VAF 16/77 reads (21%) | catalogued as COSV100814561, COSV62594884; called by muse, mutect2, varscan2
- ALDH8A1 | c.1147G>A p.D383N | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.034); catalogued as COSV99664534; called by muse, mutect2, varscan2
- ANK3 | c.3671C>T p.P1224L (on ENST00000280772 / NM_001320874.2; = p.P358L on NM_001149.3) | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs1383565358, COSV99778899; called by muse, mutect2, varscan2
- ANKRD30A | c.3994T>C p.W1332R (on ENST00000611781; = p.W1276R on NM_052997.2) | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as COSV100653113; called by muse, mutect2, varscan2
- ANKS6 | c.1537C>T p.P513S | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV100782239; called by muse, mutect2, varscan2
- AP4M1 | c.329A>T p.Y110F | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100384788; called by muse, mutect2, varscan2
- APLNR | c.365G>A p.G122D | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as COSV99951310; called by muse, mutect2
- ARHGEF10L | c.3731G>T p.G1244V | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51442468; called by muse, mutect2, varscan2
- ASTN2 | c.1105C>T p.Q369* | Nonsense Mutation (SNP) | VAF 20/70 reads (29%) | catalogued as COSV100525539; called by muse, mutect2, varscan2
- ATF2 | c.962C>T p.S321F | Missense Mutation (SNP) | VAF 13/206 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.804); catalogued as COSV99908530; called by muse, mutect2
- ATG7 | c.1663G>T p.D555Y | Missense Mutation (SNP) | VAF 90/360 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100606921; called by muse, mutect2, varscan2
- ATP11C | c.1399C>T p.R467C | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs752658279, COSV100557615; called by muse, mutect2, varscan2
- BIVM | c.606-1G>T p.X202_splice | Splice Site (SNP) | VAF 31/169 reads (18%) | catalogued as COSV99958620; called by muse, mutect2, varscan2
- BRDT | c.2255A>C p.N752T | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV100746212; called by muse, mutect2, varscan2
- BRINP3 | c.1642C>T p.H548Y | Missense Mutation (SNP) | VAF 38/175 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as rs1237194828, COSV66539691; called by muse, mutect2, varscan2
- BTNL9 | c.1466G>T p.R489M | Missense Mutation (SNP) | VAF 40/73 reads (55%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.95); catalogued as COSV100576117; called by muse, mutect2, varscan2
- CARMIL2 | c.2787C>A p.F929L | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.899); catalogued as COSV100576004; called by muse, mutect2, varscan2
- CCDC138 | c.1235A>C p.Q412P | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99718909; called by muse, mutect2, varscan2
- CCDC34 | c.131G>T p.G44V | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as COSV100156461; called by muse, mutect2, varscan2
- CCDC40 | c.1324T>A p.Y442N | Missense Mutation (SNP) | VAF 32/143 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.406); catalogued as COSV99481491; called by muse, mutect2, varscan2
- CCDC88B | c.1759G>T p.E587* | Nonsense Mutation (SNP) | VAF 12/58 reads (21%) | catalogued as COSV100105167; called by muse, mutect2, varscan2
- CCSER2 | c.1237G>T p.D413Y | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1407074124, COSV99825635; called by muse, mutect2
- CDH22 | c.1006C>A p.Q336K | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.691); catalogued as COSV100952790; called by muse, mutect2, varscan2
- CDH4 | c.431C>A p.P144H | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100848538; called by muse, mutect2, varscan2
- CDH8 | c.2125A>T p.R709W | Missense Mutation (SNP) | VAF 56/212 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54847333; called by muse, mutect2, varscan2
- CHD1 | c.4122G>T p.K1374N | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.328); catalogued as COSV99399224; called by muse, mutect2, varscan2
- CHD6 | c.2776G>T p.G926W | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100497930; called by muse, mutect2, varscan2
- CKAP2L | c.1068G>T p.K356N | Missense Mutation (SNP) | VAF 78/246 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV100198510; called by muse, mutect2, varscan2
- CNTNAP2 | c.1319C>A p.T440N | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as COSV100664062, COSV62172851; called by muse, mutect2, varscan2
- COG4 | c.1253A>G p.Q418R | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV100091455; called by muse, mutect2, varscan2
- COL1A1 | c.1769G>T p.G590V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99866703; called by muse, mutect2, varscan2
- COL4A5 | c.1234G>T p.G412* | Nonsense Mutation (SNP) | VAF 26/87 reads (30%) | catalogued as COSV100086978; called by muse, mutect2, varscan2
- CORO2B | c.1267G>A p.G423R | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.928); catalogued as rs148459295; called by muse, mutect2, varscan2
- CRHR1 | c.176C>A p.P59H | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV99523402; called by muse, mutect2, varscan2
- CRIM1 | c.313G>T p.E105* | Nonsense Mutation (SNP) | VAF 18/68 reads (26%) | catalogued as COSV99752785, COSV99754301; called by muse, mutect2, varscan2
- CSF2RA | c.1153G>T p.E385* | Nonsense Mutation (SNP) | VAF 24/104 reads (23%) | catalogued as COSV100817573; called by muse, mutect2, varscan2
- CSMD2 | c.6054C>G p.N2018K | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV99587315; called by muse, mutect2, varscan2
- CSMD3 | c.8439A>G p.L2813= (on ENST00000297405 / NM_001363185.1; = p.L2644= on NM_052900.3) | Splice Region (SNP) | VAF 18/71 reads (25%) | catalogued as COSV99828369; called by muse, mutect2, varscan2
- CST11 | c.114G>T p.M38I | Missense Mutation (SNP) | VAF 46/204 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100776860; called by muse, mutect2, varscan2
- CST11 | c.113T>A p.M38K | Missense Mutation (SNP) | VAF 47/206 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100776864; called by muse, mutect2, varscan2
- CTC1 | c.1934C>G p.P645R | Missense Mutation (SNP) | VAF 72/224 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as COSV100236242; called by muse, mutect2, varscan2
- CTNND2 | c.2044C>A p.L682M | Missense Mutation (SNP) | VAF 46/170 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV100473495; called by muse, mutect2, varscan2
- CTU2 | c.737G>C p.R246P | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99965550; called by muse, mutect2, varscan2
- CYLC1 | c.1887G>T p.M629I | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.609); catalogued as COSV61410639; called by muse, mutect2, varscan2
- CYP2C9 | c.325G>C p.G109R | Missense Mutation (SNP) | VAF 56/222 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.312); catalogued as COSV53248397, COSV99582442; called by muse, mutect2, varscan2
- DGCR2 | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.055); catalogued as COSV99593400; called by muse, mutect2, varscan2
- DGKK | c.2403C>A p.F801L | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV101052926; called by muse, mutect2, varscan2
- DNAJC6 | c.1202C>T p.T401M | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV54777101; called by muse, mutect2, varscan2
- DOCK1 | c.1967A>T p.D656V | Missense Mutation (SNP) | VAF 50/196 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as COSV99727788; called by muse, mutect2, varscan2
- DPY19L2 | c.2006G>T p.R669L | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100193014, COSV61046514; called by muse, mutect2
- DYNC1I1 | c.632-1G>T p.X211_splice | Splice Site (SNP) | VAF 35/115 reads (30%) | catalogued as COSV100267874; called by muse, mutect2, varscan2
- EDIL3 | c.369C>G p.C123W | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs761164390, COSV99674405, COSV99675326; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.2830C>T p.R944C | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.899); catalogued as rs757609510, COSV57516988; called by muse, mutect2
- ELL2 | c.1124C>A p.P375H | Missense Mutation (SNP) | VAF 33/169 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99427293; called by muse, mutect2, varscan2
- EML2 | c.1779C>G p.D593E | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99839729; called by muse, mutect2, varscan2
- ENKUR | c.320A>G p.N107S | Missense Mutation (SNP) | VAF 37/150 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as rs1386460164, COSV100482065; called by muse, mutect2, varscan2
- ENKUR | c.221C>A p.P74H | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.74); catalogued as COSV100482003, COSV100482067; called by muse, mutect2, varscan2
- EYA2 | c.1489T>A p.Y497N | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV100426587; called by muse, mutect2, varscan2
- FAM110A | c.539G>A p.R180Q | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV99856668; called by mutect2, varscan2
- FAM111B | c.1138G>A p.V380I | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100639247; called by muse, mutect2
- FAM181A | c.758T>A p.L253Q | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0.023); catalogued as COSV99967822; called by muse, mutect2, varscan2
- FASN | c.2534C>T p.P845L | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as rs756471902, COSV100147502; called by muse, mutect2, varscan2
- FGD5 | c.1261G>A p.A421T | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0.033); catalogued as rs371826302, COSV104374012; called by muse, mutect2, varscan2
- FHOD3 | c.235C>A p.Q79K | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as COSV99940525; called by muse, mutect2, varscan2
- FLOT2 | c.1216G>T p.V406L | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as COSV101204751; called by muse, mutect2, varscan2
- FMC1 | c.313C>T p.Q105* | Nonsense Mutation (SNP) | VAF 12/48 reads (25%) | catalogued as COSV99880537; called by muse, mutect2, varscan2
- FN1 | c.4258C>A p.P1420T | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100116532; called by muse, mutect2, varscan2
- FOLR3 | c.709G>T p.A237S | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.049); catalogued as rs769783918, COSV100281752; called by muse, mutect2, varscan2
- FOXP2 | c.1795C>T p.P599S | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.487); catalogued as COSV100646369; called by muse, mutect2, varscan2
- GABRA1 | c.424C>A p.P142T | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV99195766; called by muse, mutect2, varscan2
- GABRB3 | c.886A>G p.T296A | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.688); catalogued as COSV100158873; called by muse, mutect2
- GLI2 | c.1010C>T p.T337M | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.395); catalogued as rs1419274436, COSV100082645; called by muse, mutect2, varscan2
- GPR84 | c.14C>A p.S5Y | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV99909975; called by muse, mutect2, varscan2
- GRID1 | c.835A>G p.T279A | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV100022655; called by muse, mutect2, varscan2
- H2AP | c.215C>A p.A72D | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV100586908, COSV61911063; called by muse, mutect2, varscan2
- HBS1L | c.745del p.A249Rfs*15 | Frame Shift Del (DEL) | VAF 32/142 reads (23%) | catalogued as COSV63200781; called by pindel, varscan2
- HOXA3 | c.472T>C p.W158R | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV100415350; called by muse, mutect2, varscan2
- IGFN1 | c.3415G>T p.D1139Y (on ENST00000295591 / NM_001367841.1; = p.D3596Y on NM_001164586.2) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as COSV99811505; called by muse, mutect2, varscan2
- IGKV2D-28 | c.314C>A p.A105D | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV101494553; called by mutect2, varscan2
- IL17A | c.291G>T p.L97F | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.7); PolyPhen benign (0.251); catalogued as COSV100391444; called by muse, mutect2, varscan2
- IQCE | c.1526G>T p.R509L | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV100383266; called by muse, mutect2, varscan2
- ITGAE | c.2188G>T p.D730Y | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99560600; called by muse, mutect2, varscan2
- ITGB8 | c.164G>T p.C55F | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99750901; called by muse, mutect2, varscan2
- ITIH1 | c.10G>T p.A4S | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV99835048; called by muse, mutect2, varscan2
- JPH4 | c.1568C>T p.P523L | Missense Mutation (SNP) | VAF 105/474 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100436611; called by muse, mutect2, varscan2
- KCNH5 | c.2167G>T p.G723C | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV100525772; called by muse, mutect2, varscan2
- KCNJ8 | c.940A>C p.I314L | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1043556762, COSV99557430; called by muse, mutect2, varscan2
- KITLG | c.193-1G>T p.X65_splice | Splice Site (SNP) | VAF 17/60 reads (28%) | catalogued as COSV99933211; called by muse, mutect2, varscan2
- KRTAP10-6 | c.976T>A p.S326T | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.888); catalogued as COSV100552380, COSV59979899; called by muse, mutect2, varscan2
- KRTAP15-1 | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 44/203 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100481612; called by muse, mutect2, varscan2
- KRTAP24-1 | c.290C>A p.S97Y | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.77); catalogued as COSV100447359, COSV61089737; called by muse, mutect2, varscan2
- LARGE1 | c.2236G>C p.A746P | Missense Mutation (SNP) | VAF 36/190 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100504892, COSV61670964; called by muse, mutect2, varscan2
- LCT | c.1878C>A p.F626L | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV99928907; called by muse, mutect2, varscan2
- LRP1B | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV101254179; called by muse, mutect2, varscan2
- LRP1B | c.420T>G p.C140W | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101254180; called by muse, mutect2, varscan2
- LRP2 | c.12257C>A p.A4086D | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as rs578230287, COSV99787118; called by muse, mutect2, varscan2
- LRRIQ3 | c.1253G>C p.R418P | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.029); catalogued as rs770132340, COSV100598553, COSV63041590; called by muse, mutect2, varscan2
- LRRTM3 | c.293G>C p.S98T | Missense Mutation (SNP) | VAF 43/223 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.145); catalogued as COSV100791537; called by muse, mutect2, varscan2
- LYSMD3 | c.380G>T p.R127I | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as COSV100270339, COSV60058105; called by muse, mutect2, varscan2
- MCHR2 | c.143G>T p.G48V | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99911689; called by muse, mutect2, varscan2
- MED13 | c.5899G>C p.A1967P | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101180855; called by muse, mutect2, varscan2
- MRPS15 | c.260A>G p.D87G | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100117430; called by muse, mutect2, varscan2
- MRPS15 | c.259G>T p.D87Y | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100117431; called by muse, mutect2, varscan2
- MRPS31 | c.318G>T p.M106I | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as COSV100062076; called by muse, mutect2, varscan2
- MSGN1 | c.253G>A p.G85S | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as rs1040261976, COSV55262510; called by muse, mutect2, varscan2
- MUC16 | c.23887C>T p.P7963S | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); catalogued as COSV67440951; called by muse, mutect2, varscan2
- MUC16 | c.22181C>A p.S7394Y | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.996); catalogued as COSV101198802, COSV67465147; called by muse, mutect2, varscan2
- MUC16 | c.14873C>A p.T4958N | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.028); catalogued as COSV101198803; called by muse, mutect2, varscan2
- MYH1 | c.4907C>A p.A1636D | Missense Mutation (SNP) | VAF 61/183 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV99875261; called by muse, mutect2, varscan2
- MYO18A | c.5885G>T p.R1962I | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV100572017; called by muse, mutect2, varscan2
- NCKAP1L | c.1835G>T p.C612F | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.337); catalogued as COSV99514711; called by muse, mutect2, varscan2
- NCOR1 | c.790-1G>A p.X264_splice | Splice Site (SNP) | VAF 43/109 reads (39%) | catalogued as COSV99248345; called by muse, mutect2, varscan2
- NDUFS1 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 54/199 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99260624; called by muse, mutect2, varscan2
- NEDD4L | c.2472G>T p.M824I (on ENST00000400345 / NM_001144967.3; = p.M804I on NM_015277.6) | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99893878; called by muse, mutect2, varscan2
- NEU2 | c.389C>T p.T130I | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.141); catalogued as COSV99290493; called by muse, mutect2, varscan2
- NFAT5 | c.2834A>G p.N945S | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0); catalogued as rs767801967, COSV100590609, COSV63029813; called by muse, mutect2, varscan2
- NOC2L | c.1918-2A>T p.X640_splice | Splice Site (SNP) | VAF 20/102 reads (20%) | catalogued as COSV100497897; called by muse, mutect2, varscan2
- NOD1 | c.1714G>T p.G572C | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.124); catalogued as rs755565671, COSV99767894; called by muse, mutect2, varscan2
- NPY4R | c.281G>T p.C94F | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100966134, COSV65397467; called by muse, mutect2, varscan2
- NRXN3 | c.2207T>A p.L736Q (on ENST00000335750 / NM_001330195.2; = p.L363Q on NM_004796.6) | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100201952; called by muse, mutect2
- NUP160 | c.3272G>A p.R1091H | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs752680140, COSV65857052; called by muse, mutect2, varscan2
- OBSCN | c.6727C>T p.Q2243* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as rs780501894, COSV99475014; called by muse, mutect2
- OBSCN | c.10325C>A p.T3442N | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV99475015; called by muse, mutect2, varscan2
- OPALIN | c.236C>A p.P79H | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV100959584, COSV64520985; called by muse, mutect2, varscan2
- OR14K1 | c.182T>G p.L61R | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99315027; called by muse, mutect2, varscan2
- OR2M5 | c.425G>T p.G142V | Missense Mutation (SNP) | VAF 136/703 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.029); catalogued as COSV63547325; called by muse, mutect2, varscan2
- OR4A16 | c.188A>T p.Y63F | Missense Mutation (SNP) | VAF 62/276 reads (22%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.005); catalogued as COSV100125084; called by muse, mutect2, varscan2
- OR4X1 | c.873A>T p.E291D | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.059); catalogued as COSV100186603, COSV60722307; called by muse, mutect2, varscan2
- OR52E6 | c.360G>T p.M120I | Missense Mutation (SNP) | VAF 91/319 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.291); catalogued as COSV61431286; called by muse, mutect2, varscan2
- OR5D16 | c.242C>A p.P81H | Missense Mutation (SNP) | VAF 106/400 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101003874; called by muse, mutect2, varscan2
- OR5L2 | c.636G>T p.M212I | Missense Mutation (SNP) | VAF 67/261 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV101004259, COSV65723457; called by muse, mutect2, varscan2
- OR5M1 | c.611G>T p.G204V | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV73202336; called by muse, mutect2, varscan2
- OR5M1 | c.610G>T p.G204C | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101591541; called by muse, mutect2, varscan2
- OR5R1 | c.559C>A p.L187M | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); catalogued as COSV100393349, COSV100393573, COSV56572646; called by muse, mutect2, varscan2
- OTUD7B | c.1239-1G>T p.X413_splice | Splice Site (SNP) | VAF 34/68 reads (50%) | catalogued as COSV100967424; called by muse, mutect2, varscan2
- PAK1IP1 | c.169A>C p.T57P | Missense Mutation (SNP) | VAF 40/218 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99468402; called by muse, mutect2, varscan2
- PCDHB1 | c.1054del p.V352Cfs*14 | Frame Shift Del (DEL) | VAF 23/122 reads (19%) | catalogued as COSV100128192; called by mutect2, pindel, varscan2
- PCDHB5 | c.1989C>A p.D663E | Missense Mutation (SNP) | VAF 39/181 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.935); catalogued as COSV50654505, COSV99167727; called by muse, mutect2, varscan2
- PCDHGA7 | c.652G>A p.G218S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs772901140, COSV99533587; called by muse, mutect2, varscan2
- PCDHGA8 | c.34G>T p.E12* | Nonsense Mutation (SNP) | VAF 8/35 reads (23%) | catalogued as COSV99533588; called by muse, mutect2
- PCDHGA9 | c.1910C>T p.A637V | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.103); catalogued as rs377687399; called by muse, mutect2, varscan2
- PCDHGB2 | c.1545C>A p.F515L | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV99533585; called by muse, mutect2, varscan2
- PDZRN4 | c.1777G>T p.D593Y (on ENST00000402685 / NM_001164595.2; = p.D335Y on NM_013377.4) | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as rs748274458, COSV100113918; called by muse, mutect2, varscan2
- PGBD2 | c.890G>C p.W297S | Missense Mutation (SNP) | VAF 96/223 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100251907; called by muse, mutect2, varscan2
- PLXNB2 | c.5060G>T p.R1687L | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100833917, COSV63782491; called by muse, mutect2
- PPEF2 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.192); catalogued as rs1187583353, COSV99714275; called by muse, mutect2, varscan2
- PRUNE2 | c.1352C>A p.P451H | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100944318; called by muse, mutect2, varscan2
- PTPRN2 | c.1522G>T p.E508* | Nonsense Mutation (SNP) | VAF 26/114 reads (23%) | catalogued as COSV101233971, COSV67063742; called by muse, mutect2, varscan2
- REP15 | c.91G>T p.A31S | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV57300431; called by muse, mutect2, varscan2
- RNF217 | c.482A>T p.Q161L | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV101451343; called by muse, mutect2, varscan2
- RPP40 | c.143A>T p.E48V | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV100123924; called by muse, mutect2, varscan2
- RYR3 | c.3638A>G p.Y1213C | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV66786599; called by muse, mutect2, varscan2
- SAMSN1 | c.649A>T p.I217F | Missense Mutation (SNP) | VAF 61/206 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99580979; called by muse, mutect2, varscan2
- SCAI | c.1327-2A>C p.X443_splice (on ENST00000336505 / NM_001144877.3; = p.X466_splice on NM_173690.5) | Splice Site (SNP) | VAF 26/92 reads (28%) | catalogued as COSV100332382; called by muse, mutect2, varscan2
- SCFD1 | c.1765C>T p.Q589* | Nonsense Mutation (SNP) | VAF 30/92 reads (33%) | catalogued as COSV100356165; called by muse, mutect2, varscan2
- SGMS1 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.971); catalogued as rs773425601, COSV100693212; called by muse, mutect2, varscan2
- SINHCAF | c.601G>C p.A201P | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100530509; called by muse, mutect2, varscan2
- SIPA1L3 | c.2407G>T p.A803S | Missense Mutation (SNP) | VAF 68/153 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99727768; called by muse, mutect2, varscan2
- SLC17A2 | c.80C>G p.S27* | Nonsense Mutation (SNP) | VAF 9/116 reads (8%) | catalogued as COSV99614015; called by muse, mutect2
- SLC23A2 | c.1208G>T p.R403L | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV57772031; called by muse, mutect2, varscan2
- SLC24A4 | c.493C>A p.H165N | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.739); catalogued as COSV54111650; called by muse, mutect2
- SLC29A4 | c.1271G>A p.R424H | Missense Mutation (SNP) | VAF 60/210 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs565671972, COSV51876630; called by muse, mutect2, varscan2
- SLC35F3 | c.1250C>T p.P417L (on ENST00000366617 / NM_001300845.1; = p.P486L on NM_173508.4) | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.335); catalogued as COSV100784740, COSV100784798; called by muse, varscan2
- SLC8A3 | c.202C>A p.P68T | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.998); catalogued as COSV63525247; called by muse, mutect2, varscan2
- SMC1A | c.521A>C p.E174A | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as COSV100447159; called by muse, mutect2, varscan2
- SOCS6 | c.814G>T p.D272Y | Missense Mutation (SNP) | VAF 43/174 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.054); catalogued as COSV101205683; called by muse, mutect2, varscan2
- SP110 | c.1171G>A p.V391M | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.051); catalogued as COSV99283176; called by muse, mutect2
- SPAG17 | c.4999G>A p.A1667T | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs769144637, COSV100308346; called by muse, mutect2, varscan2
- SPPL2C | c.395C>G p.T132S | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as rs1318890953, COSV100233969; called by muse, varscan2
- STARD4 | c.14C>T p.S5F | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as COSV99685252; called by muse, mutect2, varscan2
- STRIP2 | c.845G>T p.G282V | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99973574; called by muse, mutect2, varscan2
- SUOX | c.1625A>G p.Y542C | Missense Mutation (SNP) | VAF 57/218 reads (26%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.704); catalogued as rs781086225, COSV99906971; called by muse, mutect2, varscan2
- SV2B | c.922G>T p.G308C | Missense Mutation (SNP) | VAF 49/183 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100370488; called by muse, mutect2, varscan2
- SYT13 | c.478C>A p.P160T | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as COSV99194660; called by muse, mutect2, varscan2
- SYT17 | c.454G>C p.D152H | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100810634; called by muse, mutect2, varscan2
- TAS2R46 | c.857T>C p.L286P | Missense Mutation (SNP) | VAF 80/416 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101114402; called by muse, mutect2, varscan2
- TBX1 | c.1175C>G p.T392S | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.036); catalogued as COSV100284015; called by muse, mutect2, varscan2
- TECPR2 | c.3446G>T p.C1149F | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100849888; called by muse, mutect2, varscan2
- TENM1 | c.4220A>G p.Q1407R | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.379); catalogued as rs1210028519, COSV100949408; called by muse, mutect2, varscan2
- TGM6 | c.28G>T p.D10Y | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99171714; called by muse, mutect2, varscan2
- TMEM132D | c.3273C>G p.Y1091* | Nonsense Mutation (SNP) | VAF 34/157 reads (22%) | catalogued as COSV101242629; called by muse, mutect2, varscan2
- TMPRSS15 | c.2461G>T p.V821L | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.187); catalogued as COSV99517273; called by muse, mutect2, varscan2
- TOGARAM2 | c.2477C>A p.A826E | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs368441564, COSV101090946, COSV65420120; called by muse, mutect2, varscan2
- UGCG | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.085); catalogued as COSV100958934; called by muse, mutect2, varscan2
- UGT2B4 | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 54/247 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV59321250; called by muse, mutect2, varscan2
- VCAN | c.3542G>T p.G1181V | Missense Mutation (SNP) | VAF 62/244 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99425068; called by muse, mutect2, varscan2
- VCAN | c.8077C>G p.L2693V | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); catalogued as COSV99425070; called by muse, mutect2, varscan2
- WDR93 | c.709C>A p.P237T | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.891); catalogued as COSV99175504; called by muse, mutect2, varscan2
- XIRP2 | c.2272C>G p.R758G (on ENST00000628543; = p.R933G on NM_152381.6) | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV54703705, COSV99740091; called by muse, mutect2, varscan2
- XIRP2 | c.5432C>G p.P1811R (on ENST00000628543; = p.P1986R on NM_152381.6) | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV54681879, COSV99740094; called by muse, mutect2, varscan2
- YWHAQ | c.412C>G p.R138G | Missense Mutation (SNP) | VAF 33/172 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.83); catalogued as COSV99430777, COSV99430926; called by muse, mutect2, varscan2
- ZAN | c.4683G>T p.M1561I | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as COSV100769407; called by muse, mutect2, varscan2
- ZCRB1 | c.599G>T p.R200L | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.524); catalogued as rs761704622, COSV99861195, COSV99861336; called by muse, mutect2, varscan2
- ZFP42 | c.388G>T p.E130* | Nonsense Mutation (SNP) | VAF 44/199 reads (22%) | catalogued as COSV58816934; called by muse, mutect2, varscan2
- ZNF200 | c.727A>T p.T243S | Missense Mutation (SNP) | VAF 33/177 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as COSV101205213; called by muse, mutect2, varscan2
- ZNF248 | c.950G>T p.G317V | Missense Mutation (SNP) | VAF 15/160 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as COSV100627505; called by muse, mutect2
- ZNF354A | c.636A>T p.K212N | Missense Mutation (SNP) | VAF 47/177 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV100234386; called by muse, mutect2, varscan2
- ZNF536 | c.3142G>T p.A1048S | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV100834880; called by muse, mutect2, varscan2
- ZNF831 | c.4177C>T p.R1393* | Nonsense Mutation (SNP) | VAF 34/157 reads (22%) | catalogued as rs767617884, COSV100925878; called by muse, mutect2, varscan2
- AC024940.1 | n.3634G>T | Splice Region (SNP) | VAF 12/64 reads (19%) | called by muse, mutect2, varscan2
- ADAMTS20 | c.2933G>T p.C978F | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- AMY2B | c.823del p.A275Qfs*18 | Frame Shift Del (DEL) | VAF 86/383 reads (22%) | called by mutect2, pindel, varscan2
- ASB6 | c.697del p.Q233Rfs*2 | Frame Shift Del (DEL) | VAF 14/89 reads (16%) | called by mutect2, pindel, varscan2
- IGKV3-15 | c.11C>A p.P4Q | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.436); called by muse, mutect2
- ITGA5 | c.2683del p.E895Kfs*15 | Frame Shift Del (DEL) | VAF 37/204 reads (18%) | called by mutect2, pindel, varscan2
- MROH1 | c.2255C>T p.P752L | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PDE1A | c.1516del p.D506Tfs*13 | Frame Shift Del (DEL) | VAF 21/104 reads (20%) | called by mutect2, pindel, varscan2
- RBP3 | c.2329G>A p.A777T | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- TNS1 | c.3938del p.G1313Afs*51 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | called by mutect2, pindel, varscan2
- ZNF26 | c.1013G>T p.G338V | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCA1 | c.4518G>T p.S1506= | Silent (SNP) | VAF 60/301 reads (20%) | catalogued as rs201151724, COSV101036674; called by muse, mutect2, varscan2
- ADO | c.222A>G p.T74= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs776969451, COSV101060416; called by muse, mutect2, varscan2
- AHNAK | c.13515C>G p.P4505= | Silent (SNP) | VAF 13/178 reads (7%) | catalogued as COSV99946269; called by muse, mutect2
- ARFGEF2 | c.1242G>A p.V414= | Silent (SNP) | VAF 43/181 reads (24%) | catalogued as COSV100904106; called by muse, mutect2, varscan2
- ASXL3 | c.3201G>A p.Q1067= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as COSV52477794; called by muse, mutect2, varscan2
- ATP6V1G3 | c.303C>T p.S101= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as COSV99810736; called by muse, mutect2, varscan2
- BCAR1 | c.2475C>T p.G825= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as rs745941069, COSV99366227; called by muse, mutect2, varscan2
- BRINP3 | c.1641C>A p.V547= | Silent (SNP) | VAF 38/177 reads (21%) | catalogued as COSV66516289; called by muse, mutect2, varscan2
- BSCL2 | c.1194C>T p.S398= | Silent (SNP) | VAF 30/120 reads (25%) | catalogued as COSV99628046; called by muse, mutect2, varscan2
- CADM3 | c.273C>T p.H91= (on ENST00000368125 / NM_001127173.3; = p.H125= on NM_021189.5) | Silent (SNP) | VAF 28/147 reads (19%) | catalogued as rs769161367, COSV63686188; called by muse, mutect2, varscan2
- CDKL5 | c.2685G>A p.P895= | Silent (SNP) | VAF 7/113 reads (6%) | catalogued as COSV101184133; called by muse, mutect2
- CFAP161 | c.252G>T p.V84= | Silent (SNP) | VAF 34/123 reads (28%) | catalogued as COSV99715396; called by muse, mutect2, varscan2
- COL3A1 | c.3867T>A p.A1289= | Silent (SNP) | VAF 38/142 reads (27%) | catalogued as COSV100482690; called by muse, mutect2, varscan2
- CSMD2 | c.1947A>T p.S649= | Silent (SNP) | VAF 28/106 reads (26%) | catalogued as COSV99587317; called by muse, mutect2, varscan2
- CTSC | c.1116T>C p.V372= | Silent (SNP) | VAF 33/140 reads (24%) | catalogued as COSV99910554; called by muse, mutect2, varscan2
- CYP2C9 | c.114G>C p.V38= | Silent (SNP) | VAF 40/224 reads (18%) | catalogued as COSV99582440; called by muse, mutect2, varscan2
- FAM47A | c.114G>T p.L38= | Silent (SNP) | VAF 34/90 reads (38%) | catalogued as COSV100649777; called by muse, mutect2, varscan2
- FLG | c.11469C>T p.S3823= | Silent (SNP) | VAF 165/841 reads (20%) | catalogued as rs1375621085, COSV100911152; called by muse, mutect2, varscan2
- FTCD | c.858C>T p.C286= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs767027376, COSV99384772; called by muse, mutect2, varscan2
- GJD2 | c.180C>A p.P60= | Silent (SNP) | VAF 23/96 reads (24%) | catalogued as COSV99290626; called by muse, mutect2, varscan2
- GPAT2 | c.1563C>A p.I521= | Silent (SNP) | VAF 37/106 reads (35%) | catalogued as COSV100853235, COSV64003590; called by muse, mutect2, varscan2
- GRIP2 | c.1561C>A p.R521= (on ENST00000619221; = p.R424= on NM_001080423.4) | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV99817066; called by muse, mutect2, varscan2
- H2AP | c.216C>G p.A72= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as COSV100586909, COSV100586913; called by muse, mutect2, varscan2
- HOPX | c.165G>T p.L55= (on ENST00000317745; = p.L73= on NM_032495.6) | Silent (SNP) | VAF 29/101 reads (29%) | catalogued as COSV100496993; called by muse, mutect2, varscan2
- IGDCC4 | c.2043G>T p.G681= | Silent (SNP) | VAF 25/82 reads (30%) | catalogued as COSV100732759; called by muse, mutect2, varscan2
- IGKV2-28 | c.21C>A p.L7= | Silent (SNP) | VAF 6/30 reads (20%) | called by mutect2, varscan2
- ITGA4 | c.1278G>T p.S426= | Silent (SNP) | VAF 23/139 reads (17%) | catalogued as COSV52001707, COSV99275884; called by muse, mutect2, varscan2
- KCNA6 | c.318G>T p.L106= | Silent (SNP) | VAF 27/119 reads (23%) | catalogued as COSV99768446; called by muse, mutect2, varscan2
- KCNJ3 | c.453C>A p.I151= | Silent (SNP) | VAF 13/81 reads (16%) | catalogued as COSV99715423, COSV99716070; called by muse, mutect2, varscan2
- LILRB4 | c.1197C>T p.D399= (on ENST00000391733 / NM_001278428.3; = p.D398= on NM_001278426.3) | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as rs1175817228, COSV99553607; called by muse, mutect2, varscan2
- MAG | c.1467C>A p.T489= | Silent (SNP) | VAF 19/110 reads (17%) | catalogued as COSV100727665; called by muse, mutect2, varscan2
- MAP3K21 | c.735G>C p.A245= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV100786244; called by muse, mutect2
- MRPL15 | c.681C>G p.A227= | Silent (SNP) | VAF 24/125 reads (19%) | catalogued as COSV99477516; called by muse, mutect2, varscan2
- MYH3 | c.4014C>G p.R1338= | Silent (SNP) | VAF 48/136 reads (35%) | catalogued as COSV99877917; called by muse, mutect2, varscan2
- MYT1L | c.1293G>T p.L431= | Silent (SNP) | VAF 38/199 reads (19%) | catalogued as COSV101219450, COSV67708093; called by muse, mutect2, varscan2
- NCKAP1L | c.1836C>T p.C612= | Silent (SNP) | VAF 18/96 reads (19%) | catalogued as rs138460707; called by muse, mutect2, varscan2
- OTOA | c.912G>T p.L304= | Silent (SNP) | VAF 33/79 reads (42%) | catalogued as COSV99623972; called by muse, mutect2, varscan2
- PCDHB13 | c.1980G>T p.V660= | Silent (SNP) | VAF 45/192 reads (23%) | catalogued as COSV99506969; called by muse, mutect2, varscan2
- POMT2 | c.870C>T p.P290= | Silent (SNP) | VAF 18/112 reads (16%) | catalogued as rs1003348896, COSV99836258; called by muse, mutect2, varscan2
- PPARGC1A | c.789C>T p.T263= | Silent (SNP) | VAF 80/365 reads (22%) | catalogued as rs1438574875, COSV99337536; called by muse, mutect2, varscan2
- PRDM9 | c.804G>C p.P268= | Silent (SNP) | VAF 27/113 reads (24%) | catalogued as COSV57002790, COSV99690020; called by muse, mutect2, varscan2
- PYGM | c.1734C>G p.L578= | Silent (SNP) | VAF 25/101 reads (25%) | catalogued as COSV51215896, COSV99376874; called by muse, mutect2, varscan2
- RANBP2 | c.4707G>T p.P1569= | Silent (SNP) | VAF 68/288 reads (24%) | catalogued as COSV99311550; called by muse, mutect2, varscan2
- RBMXL1 | c.358A>C p.R120= | Silent (SNP) | VAF 46/176 reads (26%) | catalogued as rs1197357252, COSV99555773; called by muse, mutect2, varscan2
- SAG | c.672C>A p.I224= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV101300650; called by muse, mutect2, varscan2
- SALL4 | c.2061C>T p.V687= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as COSV99409306; called by muse, mutect2, varscan2
- SERPINB9 | c.255G>T p.L85= | Silent (SNP) | VAF 34/176 reads (19%) | catalogued as COSV101046508; called by muse, mutect2, varscan2
- SLC25A4 | c.813C>T p.F271= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV99861202; called by muse, mutect2, varscan2
- SLC8A3 | c.2277C>T p.A759= (on ENST00000381269 / NM_183002.3; = p.A757= on NM_033262.4) | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as rs201244716, COSV53692952; called by muse, mutect2, varscan2
- SP110 | c.1173G>T p.V391= | Silent (SNP) | VAF 32/154 reads (21%) | catalogued as COSV99283173; called by muse, mutect2
- STX16 | c.660G>A p.E220= (on ENST00000371141 / NM_001001433.3; = p.E199= on NM_003763.6) | Silent (SNP) | VAF 16/97 reads (16%) | catalogued as rs769324515, COSV56608433; called by muse, mutect2, varscan2
- TIGD3 | c.933G>A p.R311= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV99361436; called by muse, mutect2, varscan2
- TMEM174 | c.141G>T p.L47= | Silent (SNP) | VAF 61/229 reads (27%) | catalogued as COSV99703737; called by muse, mutect2, varscan2
- TRPC4 | c.1026C>A p.V342= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as COSV58995467; called by muse, mutect2, varscan2
- TTC29 | c.30A>G p.T10= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV100283383; called by muse, mutect2, varscan2
- TTC39B | c.897G>T p.G299= | Silent (SNP) | VAF 30/175 reads (17%) | catalogued as COSV99894517; called by muse, mutect2, varscan2
- VTN | c.1422T>G p.A474= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV99412036; called by muse, mutect2, varscan2
- XIRP2 | c.7245A>G p.Q2415= (on ENST00000628543; = p.Q2590= on NM_152381.6) | Silent (SNP) | VAF 39/153 reads (25%) | catalogued as COSV99740096; called by muse, mutect2, varscan2
- ZG16B | c.6G>T p.G2= | Silent (SNP) | VAF 15/26 reads (58%) | catalogued as COSV101206749; called by muse, mutect2, varscan2
- ZNF407 | c.3021C>T p.S1007= | Silent (SNP) | VAF 45/150 reads (30%) | catalogued as rs372408214, COSV55249684; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZP4 | c.1113C>A p.P371= | Silent (SNP) | VAF 32/128 reads (25%) | catalogued as COSV63913140, COSV63913247; called by muse, mutect2, varscan2
- FOLH1B | n.1874G>A | RNA (SNP) | VAF 12/59 reads (20%) | catalogued as rs765172626; called by muse, mutect2, varscan2
- MIR296 | n.23C>T | RNA (SNP) | VAF 14/45 reads (31%) | called by muse, mutect2, varscan2
- MIR654 | n.56C>A | RNA (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- SNORD115-18 | n.34G>T | RNA (SNP) | VAF 84/421 reads (20%) | called by muse, mutect2, varscan2
- SNORD115-3 | n.2G>T | RNA (SNP) | VAF 110/508 reads (22%) | catalogued as rs925356591; called by muse, mutect2, varscan2
- SSPOP | n.14737G>T | RNA (SNP) | VAF 13/64 reads (20%) | catalogued as rs763960270, COSV100947146; called by muse, mutect2, varscan2
